Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A4IG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A4IG-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Anterior base of tongue, biopsy

- Skeletal muscle and minor salivary gland tissue, no tumor seen

B: Pharynx and base of tongue, right, partial pharyngectomy

Tumor histologic type/subtype: squamous cell carcinoma, poorly differentiated

Primary site: Per clinical note, left glossotonsillar sulcus extending into lingual tonsil

ICA-0-3

Size: 1.5 cm

carcinoma, squamous cell, NOS 8070/3

Site: oropharynx, NOS C10.9

Extent of invasion:

Angiolymphatic invasion: not identified

Perineural Invasion: not identified

Bone invasion: no bone present in specimen

fw
10/3/12

Carcinoma in situ: not identified

Surgical Margins: surgical margins of this specimen involved with tumor (red inked inferior margin deep, black ink deep margin (these margins superseded by the additional separately submitted margins)

Lymph nodes: none present in specimen

Other significant findings: none

AJCC PATHOLOGIC TNM STAGE: pT1 pNx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

C: Tonsil, margin, biopsy

- No tumor seen

D: Midline pharyngeal margin, biopsy

- No tumor seen

[page 2 of 4]
E: Pharyngeal deep margin, biopsy
- No tumor seen

F: Anterior tongue, biopsy
- No tumor seen

G: Posterior oral tongue, biopsy
- No tumor seen

H: Deep inferior pharynx, biopsy
- No tumor seen

I: Vallecula mucosa, biopsy
- No tumor seen

J: Inferior deep margin, biopsy
- No tumor seen

K: Medial base of tongue, biopsy
- No tumor seen

Clinical History:

-year-old male. Per , the patient has a T1N2M0 squamous cell carcinoma of the right base of tongue, involving the left glossotonsillar sulcus extending into the lingual tonsil.

Gross Description:

Received are eleven appropriately labeled containers.

Container A is additionally labeled "anterior base of tongue." It holds a fragment of red/brown grossly recognizable muscle approximately 2.0 x 1.6 x 0.9 cm. One surface is relatively smooth while the remaining surfaces are rough and inked blue. The specimen is serially sectioned to reveal a red/brown homogeneous cut surface and is submitted in blocks A1-A3,

Container B is additionally labeled "right pharyngectomy and base of tongue, stitch marks lateral" and holds a roughly rectangular shaped piece of tan soft tissue oriented as stated above. The tissue is 4.7 cm from lateral to medial, 4.2 cm from superior to inferior, and up to 1.3 cm from superficial to deep. One surface is covered with tan glistening nodular mucosa and notable for a 1.5 x 0.8 cm tan ulcerated lesion with raised

[page 3 of 4]
edges. The lesion comes to within 0.5 cm of the red inked inferior mucosal margin, 0.6 cm of the green inked medial mucosal margin, 1.5 cm from the yellow inked superior margin, and 2.0 cm from the blue inked lateral margin. The specimen is sectioned from medial towards lateral to reveal that the lesion on the surface extends 0.6 cm into the underlying soft tissue, to within 0.2 cm of the black inked deep margin. No additional abnormalities are noted. The majority of the lateral half of the specimen consists of red/brown unremarkable tissue.

Block Summary:

B1-B4 - Medial margin, perpendicular
B5-B7 - Sequential sections moving from medial towards lateral, bisected into superior and inferior halves
B8-B14 - Sequential sections continuing from medial towards lateral to include superior, inferior and deep margins, perpendicular
B15 - Lateral margin perpendicular,

Container C is additionally labeled "tonsil margin." It holds a 1.9 x 1.0 x 0.4 cm fragment of tan/pink glistening mucosa. One surface is roughened and inked blue. The specimen is sectioned perpendicular to the blue inked surface and submitted in blocks C1-C2,

Container D is additionally labeled "midline pharyngeal margin." It holds a strip of tan/pink to red mucosa, 3.5 x 0.6 x 0.2 cm. One surface is roughened and cauterized and inked blue. The specimen is bisected perpendicular to the blue inked surface and submitted in blocks D1-D2,

Container E is additionally labeled "pharyngeal deep margin." It holds a completely cauterized tan/brown tissue fragment, 1.4 x 0.4 x 0.2 cm. The cut surface is inked blue. The specimen is serially sectioned and submitted in block E1,

Container F is additionally labeled "anterior tongue." It holds an 8 x 4 x 4 mm fragment of tan/red soft tissue. One surface is cauterized and inked blue. The specimen is sectioned perpendicular to the blue inked surface and submitted in block F1,

Container G is additionally labeled "posterior oral tongue." It holds a 1.2 x 1.0 x 0.4 cm aggregate of two pieces of red/brown soft tissue submitted in block G1,

Container H is additionally labeled "deep inferior pharynx." It

[page 4 of 4]
holds multiple fragments of dark red cauterized tissue, 1.2 x 0.6 x 0.4 cm in aggregate. (Block H1,)

Container I is additionally labeled "vallecula mucosa." It holds a 2.1 x 1.6 x 0.4 cm piece of tan/pink mucosa. One aspect is cauterized and inked blue. The specimen is sectioned perpendicular to the blue inked surface and submitted in blocks I1 and I2,

Container J is additionally labeled "inferior deep margin." It holds a tan cauterized tissue fragment, 1.3 x 0.6 x 0.2 cm. The entire outer surface is inked blue. The specimen is serially sectioned and submitted in block J1,

Container K is additionally labeled "medial base of tongue." It holds a 1.1 x 0.4 x 0.4 cm fragment of dark red soft tissue. One aspect is cauterized and inked blue. The specimen is trisected perpendicular to the blue inked surface and submitted in block K1,

Prior Malignancy History	Prostate X	
Subsynchronous Primary Noted		X

10/3/12

Source: NCI Genomic Data Commons file dd5744d9-95d0-428a-ac0e-544cbe9cca3d (TCGA-BA-A4IG.92B76EEE-8AE3-4EF7-B746-25FB65661E61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).